Somatic mutation profile of tumor specimen TCGA-NQ-A638-01A (aliquot TCGA-NQ-A638-01A-11D-A34C-32) from TCGA case TCGA-NQ-A638, project TCGA-MESO (Mesothelioma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Mesothelioma, malignant; Tissue or organ of origin: Pleura, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 66.8 years (24,410 days).
Specimen TCGA-NQ-A638-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 74dc39a5-1bbd-43ff-8b50-7123b49f97b7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-NQ-A638-10A (Blood Derived Normal), aliquot TCGA-NQ-A638-10A-01D-A34C-32; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9383d4a1-d273-498f-bf33-2bed2f5e160b

The open-access MAF lists 49 somatic variants for this specimen: 35 protein-altering or splice-affecting, 13 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 28, Silent 13, Nonsense Mutation 3, In Frame Del 1, Frame Shift Del 1, Splice Site 1, RNA 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.823C>T p.R275C | Missense Mutation (SNP) | VAF 69/180 reads (38%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.848); catalogued as rs556436603, CM015282, COSV60787999; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GREM2 | c.9G>A p.W3* | Nonsense Mutation (SNP) | VAF 19/77 reads (25%) | catalogued as COSV58953568; called by muse, mutect2, varscan2
- KIAA0586 | c.92C>T p.A31V (on ENST00000619416 / NM_001244190.2; = p.A46V on NM_014749.5) | Missense Mutation (SNP) | VAF 25/90 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.273); catalogued as rs774053661; called by muse, mutect2, varscan2
- MROH2B | c.33G>A p.M11I | Missense Mutation (SNP) | VAF 13/31 reads (42%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs766607757; called by muse, mutect2, varscan2
- OR2T2 | c.631C>A p.P211T | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as rs755703548, COSV61617910; called by muse, mutect2, varscan2
- ZBTB45 | c.511C>T p.R171C | Missense Mutation (SNP) | VAF 14/41 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as rs779404257; called by muse, mutect2, varscan2
- ABHD14A-ACY1 | c.134C>T p.A45V | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious, low confidence (0.03); called by muse, mutect2, varscan2
- ACOT6 | c.35T>C p.I12T | Missense Mutation (SNP) | VAF 22/76 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- C16orf89 | c.629G>A p.R210K | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CCDC30 | c.2165C>T p.P722L (on ENST00000340612; = p.P679L on NM_001080850.3) | Missense Mutation (SNP) | VAF 27/49 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.487); called by muse, mutect2, varscan2
- CD33 | c.86T>G p.V29G | Missense Mutation (SNP) | VAF 24/128 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF2 | c.535C>A p.P179T | Missense Mutation (SNP) | VAF 19/99 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ELAC2 | c.1554G>C p.E518D | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ETAA1 | c.2074_2077del p.K693Ifs*2 | Frame Shift Del (DEL) | VAF 9/80 reads (11%) | called by mutect2, varscan2
- FEZF1 | c.925A>T p.I309F | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.1390_1392del p.H464del | In Frame Del (DEL) | VAF 43/109 reads (39%) | called by mutect2, pindel, varscan2
- GEMIN5 | c.2644G>T p.D882Y | Missense Mutation (SNP) | VAF 25/145 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.733); called by muse, mutect2, varscan2
- GPRC5C | c.1004C>G p.A335G (on ENST00000652232; = p.A290G on NM_018653.4) | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- KIAA0586 | c.91G>T p.A31S (on ENST00000619416 / NM_001244190.2; = p.A46S on NM_014749.5) | Missense Mutation (SNP) | VAF 26/91 reads (29%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.758); called by muse, mutect2, varscan2
- NADSYN1 | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 3/20 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.33); called by muse, mutect2
- NCOR1 | c.643A>T p.K215* | Nonsense Mutation (SNP) | VAF 31/91 reads (34%) | called by muse, mutect2
- OBI1 | c.1504A>T p.K502* | Nonsense Mutation (SNP) | VAF 30/124 reads (24%) | called by muse, mutect2, varscan2
- PCGF3 | c.44T>A p.I15N | Missense Mutation (SNP) | VAF 41/108 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- PTN | c.502G>T p.D168Y | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SATL1 | c.679C>A p.P227T (on ENST00000395409; = p.P414T on NM_001012980.2) | Missense Mutation (SNP) | VAF 22/37 reads (59%) | SIFT tolerated (1); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- SLC6A17 | c.1426G>A p.G476R | Missense Mutation (SNP) | VAF 22/109 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- SLCO4A1 | c.1757T>C p.V586A | Missense Mutation (SNP) | VAF 77/156 reads (49%) | SIFT tolerated (0.19); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SREBF1 | c.2048-17_2053delinsCA p.X683_splice | Splice Site (DEL) | VAF 16/37 reads (43%) | called by pindel, varscan2*
- SREK1IP1 | c.382G>C p.G128R | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.854); called by mutect2, varscan2
- TCHH | c.2893A>C p.K965Q | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS3 | c.233G>A p.R78K | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.16); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- TRAF7 | c.1612T>C p.Y538H | Missense Mutation (SNP) | VAF 6/48 reads (13%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- TXLNG | c.1373A>C p.Q458P | Missense Mutation (SNP) | VAF 28/56 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- VAPB | c.563dup p.Q189Afs*33 | Frame Shift Ins (INS) | VAF 31/161 reads (19%) | called by mutect2, pindel, varscan2
- VGLL2 | c.572C>T p.T191M | Missense Mutation (SNP) | VAF 9/18 reads (50%) | SIFT deleterious (0); PolyPhen benign (0.058); called by mutect2, varscan2
- ATP10B | c.4323T>A p.T1441= | Silent (SNP) | VAF 31/63 reads (49%) | called by muse, mutect2, varscan2
- CTNNB1 | c.879C>T p.F293= | Silent (SNP) | VAF 12/37 reads (32%) | called by muse, mutect2, varscan2
- DOT1L | c.1737G>C p.R579= | Silent (SNP) | VAF 21/97 reads (22%) | called by muse, mutect2, varscan2
- KATNAL2 | c.471C>T p.R157= (on ENST00000356157 / NM_001353899.1; = p.R85= on NM_031303.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/60 reads (43%) | catalogued as rs745361561; called by muse, mutect2, varscan2
- LGI4 | c.1020C>A p.G340= | Silent (SNP) | VAF 13/30 reads (43%) | catalogued as COSV100032815; called by muse, mutect2, varscan2
- MAPK11 | c.474G>T p.V158= | Silent (SNP) | VAF 18/60 reads (30%) | called by muse, mutect2, varscan2
- MYO10 | c.2145C>T p.S715= | Silent (SNP) | VAF 32/82 reads (39%) | catalogued as rs774530951; called by muse, mutect2, varscan2
- PIF1 | c.1158C>G p.T386= | Silent (SNP) | VAF 8/47 reads (17%) | called by muse, mutect2, varscan2
- PNN | c.2028A>G p.K676= | Silent (SNP) | VAF 25/85 reads (29%) | called by muse, mutect2, varscan2
- SCRIB | c.1806C>G p.L602= | Silent (SNP) | VAF 12/66 reads (18%) | called by muse, mutect2, varscan2
- SLC34A1 | c.12C>T p.Y4= | Silent (SNP) | VAF 19/75 reads (25%) | catalogued as rs747607849; called by muse, mutect2, varscan2
- TANC1 | c.3121C>T p.L1041= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV55088188; called by muse, mutect2, varscan2
- ZMAT5 | c.267G>A p.V89= | Silent (SNP) | VAF 28/44 reads (64%) | catalogued as rs1430646146; called by muse, mutect2, varscan2
- KIR3DX1 | n.112G>A | RNA (SNP) | VAF 31/85 reads (36%) | catalogued as rs758215648, COSV55597729; called by muse, mutect2, varscan2
